Somatic mutation profile of tumor specimen TCGA-56-8304-01A (aliquot TCGA-56-8304-01A-11D-2323-08) from TCGA case TCGA-56-8304, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.4 years (26,803 days).
Specimen TCGA-56-8304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbc121e6-a3c7-42cd-8ce8-deb8211b5281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8304-10A (Blood Derived Normal), aliquot TCGA-56-8304-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef40c57-c731-4733-98fa-be867cba12f2

The open-access MAF lists 274 somatic variants for this specimen: 211 protein-altering or splice-affecting, 53 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 53, Nonsense Mutation 21, Splice Site 8, Frame Shift Del 7, 3'Flank 3, Intron 2, Frame Shift Ins 2, 5'UTR 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1054+1G>T p.X352_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as COSV101037601; called by muse, mutect2, varscan2
- ACSL6 | c.842-2A>C p.X281_splice (on ENST00000379240; = p.X306_splice on NM_015256.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99734595; called by muse, mutect2, varscan2
- AFF2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100650555, COSV100651086; called by muse, mutect2, varscan2
- AHRR | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs774082083, COSV100327963; called by muse, mutect2, varscan2
- AKAP3 | c.662A>T p.K221M | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99962601; called by muse, mutect2, varscan2
- AKAP9 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200034525; called by muse, mutect2
- AKAP9 | c.8886del p.P2964Qfs*4 (on ENST00000359028; = p.P2940Qfs*4 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/173 reads (24%) | catalogued as COSV62357880; called by mutect2, pindel, varscan2
- AMOT | c.3202A>T p.I1068F (on ENST00000371959 / NM_001113490.1; = p.I659F on NM_133265.3) | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV100495535; called by muse, mutect2, varscan2
- AP3D1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs1200709958, COSV100643032; called by muse, mutect2, varscan2
- ARID1A | c.4624G>T p.E1542* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV61371858, COSV61383029; called by muse, mutect2, varscan2
- ARSF | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100839576; called by muse, mutect2, varscan2
- ATP10A | c.3035G>C p.S1012T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100791515; called by muse, mutect2, varscan2
- BACH1 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs777938054, COSV99728672; called by muse, mutect2, varscan2
- BRCA2 | c.8915T>G p.L2972W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359142, CD077813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSND | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100987659; called by muse, mutect2, varscan2
- BTBD10 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV99533907; called by muse, mutect2, varscan2
- C10orf71 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100109579; called by muse, mutect2, varscan2
- C1orf116 | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs779649781, COSV100848022; called by muse, mutect2, varscan2
- C8A | c.1613C>A p.A538E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV63483590; called by muse, mutect2, varscan2
- CACNA1E | c.3942G>T p.K1314N | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100705187; called by muse, mutect2, varscan2
- CACNG8 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99555028, COSV99555154; called by muse, varscan2
- CAMK1G | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99152037; called by muse, mutect2, varscan2
- CARMIL2 | c.3991A>T p.S1331C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV99537984; called by muse, mutect2, varscan2
- CCDC114 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100197050; called by muse, mutect2, varscan2
- CCDC18 | c.2996T>C p.I999T (on ENST00000343253 / NM_001306076.1; = p.I1000T on NM_206886.4) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs996388310, COSV100159938; called by muse, mutect2, varscan2
- CEP192 | c.4904G>A p.S1635N | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100382069; called by muse, mutect2, varscan2
- CHRM3 | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.029); catalogued as COSV99699430; called by muse, mutect2
- CHRNA1 | c.561C>A p.C187* (on ENST00000261007 / NM_001039523.3; = p.C162* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99650706; called by muse, mutect2, varscan2
- CIDEA | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100255368; called by muse, mutect2, varscan2
- CNTLN | c.3830T>C p.V1277A | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99265581; called by muse, mutect2, varscan2
- COL11A1 | c.3619G>T p.G1207C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234981157, COSV100617984; called by muse, mutect2
- COL20A1 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100491421; called by muse, mutect2
- COMMD2 | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 40/194 reads (21%) | catalogued as COSV101511906; called by muse, mutect2, varscan2
- CRIM1 | c.2861T>C p.I954T | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1346777567, COSV99754416; called by muse, mutect2, varscan2
- CSMD3 | c.10110+2T>A p.X3370_splice (on ENST00000297405 / NM_001363185.1; = p.X3201_splice on NM_052900.3) | Splice Site (SNP) | VAF 62/218 reads (28%) | catalogued as COSV99846959; called by muse, mutect2, varscan2
- CSMD3 | c.5509G>T p.G1837* (on ENST00000297405 / NM_001363185.1; = p.G1733* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 63/202 reads (31%) | catalogued as COSV99846963; called by muse, mutect2, varscan2
- CTNND2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs778030487, COSV58867380; called by muse, mutect2, varscan2
- CTSL | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100446741; called by muse, mutect2, varscan2
- CUL2 | c.1110+1G>C p.X370_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101039296; called by muse, mutect2, varscan2
- CYB5R4 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100859754; called by muse, mutect2, varscan2
- DCLK3 | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV101374123; called by muse, mutect2
- DCLRE1B | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV56727323; called by muse, mutect2, varscan2
- DDC | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779728, COSV63565223; called by muse, varscan2
- DDX50 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV101007310; called by muse, mutect2, varscan2
- DGKQ | c.2316-2A>G p.X772_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99298214; called by muse, mutect2, varscan2
- DHX8 | c.2337C>G p.F779L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99292609; called by muse, mutect2, varscan2
- DMRT3 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99506071; called by muse, mutect2, varscan2
- ECM1 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.75); catalogued as COSV100682275; called by muse, mutect2
- EFNA3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1250131315, COSV100860874; called by muse, mutect2, varscan2
- EGFR | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294789; called by muse, mutect2, varscan2
- EP400 | c.6241G>A p.A2081T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100202209; called by muse, mutect2, varscan2
- EPB41L3 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV100550179; called by muse, mutect2, varscan2
- FAT4 | c.7852C>G p.Q2618E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100630081, COSV100630689; called by muse, mutect2
- FBXO17 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.327); catalogued as COSV53070879, COSV99494343; called by muse, mutect2, varscan2
- FMN2 | c.4534G>T p.D1512Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147037; called by muse, mutect2, varscan2
- FUT9 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100134328; called by muse, mutect2, varscan2
- GAD2 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs993166149, COSV99393990; called by muse, mutect2, varscan2
- GBA3 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101545568; called by muse, mutect2, varscan2
- GMDS | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 34/142 reads (24%) | catalogued as COSV101071988; called by muse, mutect2, varscan2
- HACE1 | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99494251; called by muse, mutect2
- HELB | c.1232G>T p.R411I | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV99922202; called by muse, mutect2, varscan2
- HNF1A | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as CM112118, COSV99982983; called by muse, mutect2, varscan2
- HOXA1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99761407; called by muse, mutect2, varscan2
- HS3ST4 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1198822490, COSV100502940, COSV58821711; called by muse, mutect2, varscan2
- HS3ST5 | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100451357; called by muse, mutect2, varscan2
- HSPA6 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100554313; called by muse, mutect2, varscan2
- ICE1 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99665662; called by muse, mutect2, varscan2
- ICE1 | c.4684G>C p.D1562H | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99665667; called by muse, mutect2, varscan2
- ICE1 | c.6361G>T p.D2121Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56826745; called by muse, mutect2, varscan2
- IFIT5 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV100877967; called by muse, mutect2, varscan2
- IL1RL1 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as rs553618200, COSV99294513; called by muse, mutect2, varscan2
- INPP5D | c.2915C>T p.P972L (on ENST00000445964 / NM_001017915.3; = p.P971L on NM_005541.5) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100856917; called by muse, mutect2, varscan2
- ITPRIPL2 | c.355A>T p.S119C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101198231; called by muse, mutect2, varscan2
- KAT6A | c.4051T>G p.F1351V | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99705860; called by muse, mutect2
- KCNC2 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV100129831; called by muse, mutect2, varscan2
- KCNF1 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV54463304, COSV54465309, COSV99705867; called by muse, mutect2, varscan2
- KCTD16 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV101568885; called by muse, mutect2
- KIF14 | c.1980G>T p.W660C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284186809, COSV100951070; called by muse, mutect2, varscan2
- KIR2DL1 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 94/517 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); catalogued as COSV99383639; called by muse, mutect2, varscan2
- KLHL32 | c.688T>G p.Y230D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100987490; called by muse, mutect2
- KLHL5 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99785850; called by muse, mutect2, varscan2
- KLRF1 | c.352T>A p.W118R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684546; called by muse, mutect2, varscan2
- KRT2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100548306; called by muse, mutect2, varscan2
- KRTAP10-10 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 110/398 reads (28%) | catalogued as rs1555937362, COSV100555411; called by muse, mutect2, varscan2
- LAD1 | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100943944; called by muse, mutect2, varscan2
- LAMB4 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780322560, COSV99225547; called by muse, mutect2, varscan2
- LAMC1 | c.1297G>T p.G433* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | catalogued as COSV99280395; called by muse, mutect2, varscan2
- LHFPL5 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100799016; called by muse, mutect2, varscan2
- LIG4 | c.1314C>G p.Y438* | Nonsense Mutation (SNP) | VAF 9/229 reads (4%) | catalogued as COSV100800060; called by muse, mutect2
- LPIN3 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100953133; called by muse, mutect2
- LRP1B | c.7505G>T p.R2502I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV101250860, COSV101260642; called by muse, mutect2, varscan2
- LRP2 | c.2868C>A p.Y956* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99790196; called by muse, mutect2, varscan2
- LRRN2 | c.1740C>A p.H580Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV100912962; called by muse, mutect2, varscan2
- LSAMP | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV100372744, COSV61300700; called by muse, mutect2, varscan2
- MAML2 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101594190; called by muse, mutect2, varscan2
- MAP2 | c.5116T>G p.S1706A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV99561627; called by muse, mutect2, varscan2
- MARK2 | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100159137, COSV59287445; called by muse, mutect2
- MARK2 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100159139; called by muse, mutect2
- MBL2 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906411; called by muse, mutect2, varscan2
- MELTF | c.1431C>A p.H477Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56384766, COSV99586597; called by muse, mutect2, varscan2
- MFAP5 | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100848191; called by muse, mutect2, varscan2
- MME | c.196+1G>T p.X66_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100852535, COSV64706018; called by muse, mutect2, varscan2
- MPPED1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV100501336; called by muse, mutect2, varscan2
- MPZL2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV99635303; called by muse, mutect2, varscan2
- MSC | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100335893; called by muse, mutect2, varscan2
- MTDH | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV60347505; called by muse, mutect2
- MTDH | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs756601591, COSV100292775; called by muse, mutect2, varscan2
- MTO1 | c.2017G>T p.G673* (on ENST00000370300 / NM_133645.3; = p.G648* on NM_012123.4) | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100940553; called by muse, mutect2, varscan2
- MUC16 | c.40966G>T p.G13656C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101110082; called by muse, mutect2, varscan2
- MYO10 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 18/424 reads (4%) | catalogued as COSV101569836; called by muse, mutect2
- MYO6 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as rs369889326; called by muse, mutect2, varscan2
- NAPEPLD | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100440048; called by muse, mutect2, varscan2
- NEXMIF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV50031628; called by muse, mutect2, varscan2
- NLRP11 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100789811; called by muse, mutect2, varscan2
- NOTCH4 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100900998, COSV66680737; called by muse, mutect2, varscan2
- NR4A1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1398271962, COSV54485035, COSV99671727; called by muse, mutect2
- NSD3 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100388917; called by muse, mutect2, varscan2
- OGDHL | c.2993C>T p.T998I | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100934503; called by muse, mutect2, varscan2
- OGT | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65481792; called by muse, mutect2, varscan2
- OR10AG1 | c.340T>A p.Y114N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100400199; called by muse, mutect2, varscan2
- OR2G3 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180756; called by muse, mutect2, varscan2
- OR2L3 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 66/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63456236; called by muse, mutect2, varscan2
- OR52N4 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1457138401, COSV100421757, COSV57892989; called by muse, mutect2, varscan2
- OR52N5 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100399770; called by muse, mutect2, varscan2
- OR5B12 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs371730905; called by muse, mutect2, varscan2
- OR6N1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs1009305414, COSV58650097; called by muse, mutect2
- OTOF | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as COSV99718921; called by muse, mutect2, varscan2
- OTULIN | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.888); catalogued as rs867597034; called by muse, mutect2
- PAPPA | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs1299152909, COSV100075236; called by muse, mutect2, varscan2
- PCDH10 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99994460; called by muse, mutect2, varscan2
- PCLO | c.12737G>A p.R4246K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV100437561, COSV61656448; called by muse, mutect2, varscan2
- PDE11A | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99614820; called by muse, mutect2, varscan2
- PDE7B | c.663C>G p.N221K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100368260; called by muse, mutect2, varscan2
- PGM1 | c.1599+2T>C p.X533_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100936673; called by muse, mutect2, varscan2
- PIK3CG | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | catalogued as COSV100783163; called by muse, mutect2, varscan2
- PLPPR4 | c.1241G>T p.S414I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100926923; called by muse, mutect2, varscan2
- PNPLA3 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99337313; called by muse, mutect2, varscan2
- POLE | c.6605C>T p.T2202M | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs764457707, COSV57677299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100856103; called by muse, mutect2, varscan2
- PRMT8 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV54218064, COSV99713679; called by muse, mutect2, varscan2
- PRRX1 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs777193663, COSV99510286; called by muse, mutect2, varscan2
- PSMD1 | c.1563G>T p.L521F | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100433883; called by muse, mutect2, varscan2
- PTOV1 | c.663C>A p.D221E | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99682005; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1606A>G p.N536D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100741452; called by muse, mutect2, varscan2
- RASAL1 | c.1148T>A p.L383Q | Missense Mutation (SNP) | VAF 128/499 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99922116; called by muse, mutect2, varscan2
- REST | c.2974T>C p.S992P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100471319; called by muse, mutect2, varscan2
- RIC1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99317960; called by muse, mutect2, varscan2
- RIMBP2 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55465593, COSV99900436; called by muse, mutect2
- ROBO3 | c.1073C>G p.A358G | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101185190; called by muse, mutect2, varscan2
- RP1L1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1563126267, COSV101223607; called by muse, mutect2, varscan2
- RTTN | c.5362C>A p.P1788T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV99733766; called by muse, mutect2, varscan2
- SAMD7 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.198); catalogued as COSV100157070; called by muse, mutect2, varscan2
- SAMHD1 | c.1231A>T p.T411S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV99484307; called by muse, mutect2
- SASH1 | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.052); catalogued as COSV100821437; called by muse, mutect2, varscan2
- SCN3A | c.2015C>A p.P672Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV51805184, COSV99328453; called by muse, mutect2, varscan2
- SERPINA10 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100004027; called by muse, mutect2, varscan2
- SIAH1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99589503; called by muse, mutect2, varscan2
- SLC12A5 | c.1450G>A p.V484I (on ENST00000454036 / NM_001134771.2; = p.V461I on NM_020708.5) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as rs201487205, COSV99716797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A5 | c.2636T>A p.M879K (on ENST00000454036 / NM_001134771.2; = p.M856K on NM_020708.5) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99716798; called by muse, mutect2, varscan2
- SLC22A13 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV100314677; called by muse, mutect2, varscan2
- SLITRK2 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.635); catalogued as COSV59424218, COSV59430161; called by muse, mutect2, varscan2
- SMR3B | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | PolyPhen possibly damaging (0.526); catalogued as rs1464029611, COSV100513449; called by muse, mutect2, varscan2
- SPG7 | c.1247G>T p.G416V (on ENST00000268704; = p.G423V on NM_003119.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV99245415; called by muse, mutect2, varscan2
- SPIB | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99570147; called by muse, mutect2, varscan2
- SPTA1 | c.5708T>C p.I1903T | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV100934955; called by muse, mutect2
- SPTAN1 | c.5209G>A p.D1737N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs750748842, COSV100823992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRP68 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100326272; called by muse, mutect2, varscan2
- ST7L | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100573889; called by muse, mutect2, varscan2
- STAB2 | c.5462T>A p.V1821D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV101186286; called by muse, mutect2, varscan2
- SUPT5H | c.2720G>T p.S907I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100782147, COSV63239301; called by muse, mutect2, varscan2
- SV2B | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.912); catalogued as COSV100370992; called by muse, mutect2, varscan2
- SV2C | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100456011, COSV100456797; called by muse, mutect2
- SYNE1 | c.4928C>T p.A1643V (on ENST00000367255 / NM_182961.4; = p.A1650V on NM_033071.3) | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs753598584, COSV54943251, COSV55051913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1L | c.5155G>T p.D1719Y | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV99645374; called by muse, mutect2, varscan2
- TBXT | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99752023; called by muse, mutect2
- TG | c.7072G>A p.D2358N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603069; called by muse, mutect2, varscan2
- TJP1 | c.3419A>T p.Y1140F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.062); catalogued as COSV100633147; called by muse, mutect2, varscan2
- TMEM117 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); catalogued as COSV99863648; called by muse, mutect2, varscan2
- TMEM130 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100228990; called by muse, mutect2
- TNK2 | c.213A>T p.K71N | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV100361669; called by muse, mutect2, varscan2
- TNNI3 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as CM040497, COSV100787932, COSV100788023; called by muse, mutect2, varscan2
- TNR | c.2805C>A p.S935R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54898167, COSV99688832; called by muse, mutect2, varscan2
- TRIM3 | c.1042A>C p.K348Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100624540; called by muse, mutect2, varscan2
- TRPS1 | c.3004A>T p.S1002C (on ENST00000220888 / NM_001330599.2; = p.S1015C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99634209; called by muse, mutect2, varscan2
- TSHZ3 | c.2339A>T p.Y780F | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99552673; called by muse, mutect2, varscan2
- TTC14 | c.1825G>T p.G609C | Missense Mutation (SNP) | VAF 176/435 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99870182, COSV99870585; called by muse, mutect2, varscan2
- TTN | c.77306G>A p.R25769K (on ENST00000591111; = p.R18345K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | PolyPhen benign (0.015); catalogued as COSV100629013; called by muse, mutect2, varscan2
- UBQLN3 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100293960; called by muse, mutect2, varscan2
- UMOD | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV100208677; called by muse, mutect2, varscan2
- USP17L2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as rs1372618166, COSV100414727; called by muse, mutect2, varscan2
- VLDLR | c.1876A>T p.S626C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101173240; called by muse, mutect2, varscan2
- WDR88 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs760075210, COSV99404334; called by muse, mutect2, varscan2
- WNT3 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs1314013087, COSV99843426; called by muse, mutect2, varscan2
- ZNF17 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100300172; called by muse, mutect2, varscan2
- ZNF208 | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV101237201, COSV68113543; called by muse, mutect2, varscan2
- ZNF683 | c.27A>T p.L9F | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100853740; called by muse, mutect2, varscan2
- ZNF783 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100954298; called by muse, mutect2, varscan2
- ZNF80 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100352140; called by muse, mutect2, varscan2
- ADAM22 | c.2231del p.G744Afs*4 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2572_2573del p.A858Rfs*212 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- DDX19B | c.195_196insGG p.I66Gfs*27 | Frame Shift Ins (INS) | VAF 71/288 reads (25%) | called by mutect2, pindel, varscan2
- IGHA2 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KMT2D | c.6905del p.P2302Qfs*20 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- NPRL3 | c.686del p.F229Sfs*14 (on ENST00000611875 / NM_001077350.3; = p.F204Sfs*14 on NM_001039476.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PCDHB1 | c.1442dup p.L481Ffs*3 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- RAB6D | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A1 | c.3643C>G p.Q1215E | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TSPAN11 | c.277-3_285del p.X93_splice | Splice Site (DEL) | VAF 46/150 reads (31%) | called by pindel, varscan2
- USP54 | c.4319_4329del p.S1440* | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel
- ZNF331 | c.437_438del p.L146Qfs*10 | Frame Shift Del (DEL) | VAF 33/145 reads (23%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.1125T>C p.N375= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV100416929; called by muse, mutect2, varscan2
- AQP12A | c.312G>T p.A104= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100538688, COSV61837805; called by muse, mutect2, varscan2
- ARFGEF3 | c.4527C>T p.S1509= | Silent (SNP) | VAF 42/260 reads (16%) | catalogued as rs781523472, COSV52450258; called by muse, mutect2, varscan2
- ATP13A2 | c.600C>T p.S200= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1244051238, COSV100454419; called by muse, mutect2
- BCAR1 | c.510G>C p.G170= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV99367324; called by muse, mutect2, varscan2
- BIN2 | c.306C>T p.I102= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as rs1469053591, COSV99909707; called by muse, mutect2, varscan2
- CASP5 | c.177A>G p.V59= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99508076; called by muse, mutect2
- CCDC190 | c.681C>A p.P227= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100905844; called by muse, mutect2
- CCDC69 | c.81C>T p.P27= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV100815236; called by muse, mutect2, varscan2
- CSRP1 | c.378C>G p.V126= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100384586; called by muse, mutect2, varscan2
- DACT1 | c.1662G>T p.L554= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100242104; called by muse, mutect2, varscan2
- DNAAF3 | c.714C>T p.V238= (on ENST00000524407 / NM_001256715.2; = p.V285= on NM_178837.4) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1264672206, COSV61279658; called by muse, mutect2, varscan2
- DNAJC6 | c.2436C>T p.A812= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99675604; called by muse, mutect2, varscan2
- ERICH3 | c.4077G>T p.V1359= | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as COSV100445683; called by muse, mutect2, varscan2
- FANCI | c.1935G>A p.L645= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV100168519; called by muse, mutect2, varscan2
- GLIPR1L2 | c.327C>T p.V109= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV57553563, COSV57555460; called by muse, mutect2, varscan2
- GREB1 | c.3102G>T p.P1034= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs370781434, COSV99303766; called by muse, mutect2, varscan2
- HK1 | c.847C>A p.R283= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100067282; called by muse, mutect2
- KCNA4 | c.1428G>A p.R476= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100069251; called by muse, mutect2, varscan2
- KCTD11 | c.237G>T p.L79= (on ENST00000333751 / NM_001363642.1; = p.L40= on NM_001002914.2) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99341969; called by muse, mutect2, varscan2
- LRRTM1 | c.624G>A p.L208= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs1472777485, COSV99703139; called by muse, mutect2, varscan2
- LYST | c.2556A>T p.V852= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV101090260; called by muse, mutect2, varscan2
- MAP3K20 | c.234T>C p.Y78= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs1411004433, COSV100169501; called by muse, mutect2, varscan2
- MYH15 | c.129A>G p.L43= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99844268; called by muse, mutect2, varscan2
- NPY2R | c.447C>T p.H149= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100279902; called by muse, mutect2, varscan2
- NUP210L | c.4161C>A p.P1387= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99669056; called by muse, mutect2, varscan2
- OR2H1 | c.936C>T p.S312= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101009910, COSV101009928; called by muse, mutect2
- OR4D6 | c.645G>T p.L215= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV100271828; called by muse, mutect2, varscan2
- OR4K5 | c.258G>T p.L86= | Silent (SNP) | VAF 76/364 reads (21%) | catalogued as COSV100262612; called by muse, mutect2, varscan2
- OR52A5 | c.243C>A p.P81= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100263568, COSV56614758; called by muse, mutect2, varscan2
- OR5AS1 | c.69C>A p.L23= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV57982869; called by muse, mutect2, varscan2
- PABPC5 | c.549A>G p.P183= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100442677; called by muse, mutect2, varscan2
- PABPN1 | c.594C>T p.V198= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs371658709, COSV99391265; called by muse, mutect2, varscan2
- PCDHB5 | c.669C>G p.S223= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as COSV50648633, COSV99169477; called by muse, mutect2, varscan2
- PCOLCE | c.1314C>G p.P438= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99775021; called by muse, mutect2
- PHLPP2 | c.3462C>T p.P1154= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs770590778, COSV62426880, COSV62427779; called by muse, mutect2, varscan2
- PRDM7 | c.909G>A p.E303= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100371349; called by muse, mutect2, varscan2
- PTEN | c.669G>A p.K223= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100911312; called by muse, mutect2, varscan2
- REG1A | c.459T>A p.P153= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99286973; called by muse, mutect2, varscan2
- RXRG | c.756C>G p.S252= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100717849, COSV63232949; called by muse, mutect2, varscan2
- SCARB2 | c.1425C>T p.L475= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs780985651, COSV99358117; called by muse, mutect2, varscan2
- SLC18A3 | c.651G>T p.A217= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100340849, COSV60327563; called by muse, mutect2, varscan2
- SMARCA1 | c.63C>T p.I21= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100946714; called by muse, mutect2, varscan2
- SPARCL1 | c.822A>G p.A274= | Silent (SNP) | VAF 89/234 reads (38%) | catalogued as COSV99215881; called by muse, mutect2, varscan2
- SPEF2 | c.3078T>C p.F1026= | Silent (SNP) | VAF 50/86 reads (58%) | catalogued as COSV100608837; called by muse, mutect2, varscan2
- SV2C | c.891C>A p.A297= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100456798; called by muse, mutect2
- TM4SF19 | c.510T>G p.V170= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99879450; called by muse, mutect2, varscan2
- TMEM179B | c.228C>T p.Y76= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs772908332, COSV99585464; called by muse, mutect2, varscan2
- TMEM200C | c.1815C>T p.S605= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV101274866; called by muse, mutect2, varscan2
- TPR | c.5439A>T p.T1813= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100824243; called by muse, mutect2, varscan2
- WDHD1 | c.3000A>G p.V1000= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100777649; called by muse, mutect2, varscan2
- ZBED1 | c.858G>A p.V286= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as COSV100586056; called by muse, mutect2, varscan2
- ZFX | c.342A>G p.P114= | Silent (SNP) | VAF 102/250 reads (41%) | catalogued as COSV100458088; called by muse, mutect2, varscan2
- CCDC61 | c.-38T>A | 5'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99625715; called by muse, mutect2, varscan2
- CEP295 | chr11:93733591 C>T | 3'Flank (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178056068 G>T | 3'Flank (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178056069 G>T | 3'Flank (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.557C>A | RNA (SNP) | VAF 11/70 reads (16%) | catalogued as COSV55602309, COSV99683642; called by muse, mutect2, varscan2
- TEX2 | c.2177-16G>T | Intron (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99367477; called by muse, mutect2, varscan2
- TTN | c.10361-5041G>T | Intron (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100629015; called by muse, mutect2, varscan2
- VPS11 | c.-452A>G | 5'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100333992; called by muse, mutect2, varscan2
- ZNF99 | c.*595G>T | 3'UTR (SNP) | VAF 22/67 reads (33%) | catalogued as COSV101233964; called by muse, varscan2
- ZNF99 | c.*594T>C | 3'UTR (SNP) | VAF 22/66 reads (33%) | catalogued as rs528502137, COSV101233732, COSV101233966; called by muse, varscan2
